Surgical pathology report (de-identified scan), TCGA case TCGA-77-7337, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7337-01A (Primary Tumor).

[page 1 of 2]
LEFT PNEUMONECTOMY AND LYMPH NODES

Clinical Details:

Nil supplied.

Two specimens submitted:

1: (L) LUNG

Macroscopy:

The specimen consists of a left lung which, in the inflated state, measures 200 mm in height x 165 x 60 mm. Fatty and fibrous adhesions are attached to the apex of the upper lobe where there is a scarred area approximately 35 mm in diameter. The pleura is slightly roughened over the mediastinal aspect of the upper lobe, approximately 50 mm in maximum dimension, under which a tumour is palpable. Fatty tissue to a depth of 40 mm is present inferior to the bronchial resection margin and this contains numerous lymph nodes which are small and black. Numerous large lymph nodes, which measure up to 35 mm in maximum dimension, are present superior to the bronchial resection margin. On cut surfaces the tumour is seen to be 55 mm in maximal dimension, poorly circumscribed, soft and grey and black, but with a necrotic centre. It extends right up to the pleura on the hilar surface of the lung and also to the pleura in the oblique fissure. The tumour appears to be arising from a segmental bronchus, probably that of the apicoposterior bronchus of the upper lobe. It is well clear of the bronchial resection margin. Uninvolved tissue between the tumour and the apex of the upper lobe is generally indurated and that in the basal aspect of the lobe is collapsed. Large black lymph nodes are present around major segmental bronchi in the lower lobe. No tumour is evident in the lower lobe and the parenchyma is generally normal-appearing apart from an area approximately 10 mm in maximum dimension towards the base which appears to be an area of haemorrhage. [Lymph nodes inferior to the left main bronchus are sampled in 1A-1D; those superior to the left main bronchus are sampled in 1E-1I; blocks F-G contain one large lymph node; TS of bronchial resection margin in 1J; adjacent TS in 1K; segmental bronchus with tumour in 1L-1M; tumour plus pleura on hilar surface in 1N-1P; tumour plus pleura and adjacent lung in the oblique fissure in 1Q-1R; tumour with adjacent lung in 1S; further lymph nodes around bronchus in 1T; apex of upper lobe in 1U; tissue from base of upper lobe in 1V; bronchus and lymph nodes to lower lobe in 1W; tissue from apex of lower lobe in 1X and from base of lower lobe (probable area of haemorrhage) in 1Y].

Microscopy:

Sections show a moderately differentiated keratinising squamous cell carcinoma which completely occludes a segmental bronchus. There is no evidence of lymphatic or vascular invasion, but tumour directly invades several hilar lymph nodes. Tumour is clear of the pleura in all sections, and is also clear of the bronchial resection margin. Lung distal to the tumour shows marked secondary obstructive changes including active airway inflammation and organising pneumonia. Tissue from the lower lobe shows no definite pathological features.

Conclusion:

Left pneumonectomy: Squamous cell carcinoma; pathological stage T2 N1.

2: NO. 5 NODE

Macroscopy:

The specimen consists of three pieces of rubbery dark-brown tissue, 10 mm, 10 mm and 5 mm in maximum dimension. [The largest piece is bisected and the whole specimen is in block 2A]. [ET]

Microscopy:

Sections show lymph nodes in which there are reactive changes but no evidence of metastatic carcinoma.

Conclusion:

No. 5 lymph node: No evidence of malignancy.

[page 2 of 2]
T-28000 M-80703 P1-03000
T-C4000 M-09410 P1-03000

Reported by Dr [REDACTED]
Pathology Registrar/Anatomical Pathologist
[REDACTED]

[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 113ac8b8-e4a3-4465-998f-1addd7aa97a5 (TCGA-77-7337.486787B7-4D3F-4F98-85DF-8DAA3976BFB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).